Somatic mutation profile of tumor specimen ALCH-ADP3-TTP1-A (aliquot ALCH-ADP3-TTP1-A-1-0-D-A581-36) from ALCHEMIST case ALCH-ADP3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.5 years (27,942 days).
Specimen ALCH-ADP3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 520b6add-4fc8-4646-bc66-fd59c6e3e0ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADP3-NB1-A (Blood Derived Normal), aliquot ALCH-ADP3-NB1-A-1-0-D-A581-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/147d0613-d2f3-4154-820c-8fb6e0b5c856

The open-access MAF lists 66 somatic variants for this specimen: 42 protein-altering or splice-affecting, 14 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 14, Intron 6, Nonsense Mutation 4, RNA 1, 5'UTR 1, 3'Flank 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 134/1152 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 93/497 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs587782529, CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTB | c.1027G>C p.G343R | Missense Mutation (SNP) | VAF 98/742 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV59317762; called by muse, mutect2, varscan2
- ARID1A | c.1528C>T p.Q510* | Nonsense Mutation (SNP) | VAF 52/1376 reads (4%) | catalogued as COSV61374730; called by muse, mutect2
- CBFB | c.339G>A p.W113* | Nonsense Mutation (SNP) | VAF 37/687 reads (5%) | catalogued as COSV51996629; called by muse, mutect2
- CHD3 | c.3905T>C p.I1302T | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.185); catalogued as rs778853591; called by muse, mutect2
- COL6A5 | c.115G>C p.D39H | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55206604; called by mutect2, varscan2
- JMJD1C | c.1306C>G p.Q436E | Missense Mutation (SNP) | VAF 52/934 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99062893; called by muse, mutect2
- KMT2A | c.11357G>A p.R3786H | Missense Mutation (SNP) | VAF 79/653 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555052977, COSV63290561; called by muse, mutect2, varscan2
- LANCL1 | c.890A>C p.K297T | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as rs147390013; called by muse, mutect2
- MAB21L1 | c.316C>A p.R106S | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV59787960; called by muse, mutect2, varscan2
- MMP9 | c.2042G>A p.R681H | Missense Mutation (SNP) | VAF 136/1211 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774687719, COSV63434571; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MROH2B | c.1636G>T p.V546L | Missense Mutation (SNP) | VAF 29/602 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.073); catalogued as rs756584525; called by muse, mutect2
- PIGO | c.2455G>T p.G819C | Missense Mutation (SNP) | VAF 46/474 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV53052529; called by muse, mutect2
- RADX | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 34/400 reads (9%) | catalogued as rs975208319, COSV65319438; called by muse, mutect2
- SMIM3 | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 51/303 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.883); catalogued as rs780742167; called by muse, mutect2, varscan2
- TBX5 | c.162C>G p.I54M | Missense Mutation (SNP) | VAF 58/1116 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV100092359; called by muse, mutect2
- XPNPEP2 | c.639G>T p.G213= | Splice Region (SNP) | VAF 24/196 reads (12%) | catalogued as rs1245498153; called by muse, varscan2
- XYLT1 | c.1774C>T p.R592W | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1420433386, COSV54479298, COSV99763118; called by muse, mutect2, varscan2
- ADAM7 | c.1424G>A p.G475D | Missense Mutation (SNP) | VAF 20/490 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGEF7 | c.1004A>C p.E335A (on ENST00000375741 / NM_001113511.2; = p.E157A on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/341 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ATG2A | c.714G>T p.E238D | Missense Mutation (SNP) | VAF 20/467 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); called by muse, mutect2
- CLDN1 | c.266T>A p.L89H | Missense Mutation (SNP) | VAF 24/602 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- CPZ | c.229T>A p.S77T (on ENST00000360986 / NM_001014447.3; = p.S66T on NM_003652.3) | Missense Mutation (SNP) | VAF 25/222 reads (11%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- DNHD1 | c.12392C>T p.A4131V | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DOCK6 | c.6104A>G p.N2035S | Missense Mutation (SNP) | VAF 68/439 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM47C | c.268C>A p.P90T | Missense Mutation (SNP) | VAF 58/449 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- HAPLN4 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 31/243 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IDS | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 86/910 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- IL1RAPL2 | c.1053A>T p.L351F | Missense Mutation (SNP) | VAF 65/387 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- KCND2 | c.319C>A p.P107T | Missense Mutation (SNP) | VAF 124/1280 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIF1C | c.2462G>T p.S821I | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAP7D3 | c.2149G>C p.E717Q | Missense Mutation (SNP) | VAF 20/567 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NOTCH3 | c.2608T>A p.S870T | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- NT5E | c.100A>T p.T34S | Missense Mutation (SNP) | VAF 54/608 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- NT5E | c.101C>T p.T34I | Missense Mutation (SNP) | VAF 54/620 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); called by muse, mutect2
- PCDH10 | c.1287C>A p.Y429* | Nonsense Mutation (SNP) | VAF 42/224 reads (19%) | called by muse, mutect2, varscan2
- PCYOX1 | c.1202G>T p.G401V | Missense Mutation (SNP) | VAF 81/810 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.091); called by muse, mutect2
- SKIL | c.197G>C p.G66A | Missense Mutation (SNP) | VAF 83/385 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TP53BP1 | c.3262C>G p.Q1088E | Missense Mutation (SNP) | VAF 56/392 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP11 | c.1804G>T p.D602Y (on ENST00000218348; = p.D559Y on NM_001371072.1) | Missense Mutation (SNP) | VAF 78/653 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZC3H14 | c.1676G>T p.G559V | Missense Mutation (SNP) | VAF 177/1144 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CACNB4 | c.1035G>A p.L345= | Silent (SNP) | VAF 62/677 reads (9%) | called by muse, mutect2
- EPHA10 | c.1902T>C p.H634= | Silent (SNP) | VAF 52/330 reads (16%) | called by muse, mutect2, varscan2
- ETV3 | c.663C>A p.G221= | Silent (SNP) | VAF 32/190 reads (17%) | called by muse, mutect2, varscan2
- FOXO4 | c.1230G>T p.T410= | Silent (SNP) | VAF 46/232 reads (20%) | catalogued as COSV58575626, COSV58576446; called by muse, mutect2, varscan2
- LONRF3 | c.699C>A p.L233= | Silent (SNP) | VAF 12/254 reads (5%) | called by muse, mutect2
- LRRC3B | c.546C>A p.G182= | Silent (SNP) | VAF 22/310 reads (7%) | catalogued as rs769674309; called by muse, mutect2
- NSUN2 | c.1065G>C p.L355= | Silent (SNP) | VAF 87/870 reads (10%) | catalogued as COSV52957232; called by muse, mutect2, varscan2
- RTL1 | c.3070A>C p.R1024= | Silent (SNP) | VAF 47/381 reads (12%) | called by muse, mutect2, varscan2
- RTL4 | c.552C>T p.F184= | Silent (SNP) | VAF 31/286 reads (11%) | catalogued as rs138326550, COSV61206186, COSV61207302; called by muse, mutect2, varscan2
- SLITRK2 | c.1497G>T p.L499= | Silent (SNP) | VAF 35/331 reads (11%) | called by muse, mutect2, varscan2
- USH2A | c.10968C>T p.F3656= | Silent (SNP) | VAF 60/1356 reads (4%) | catalogued as rs866178289; called by muse, mutect2
- VPS26B | c.75C>A p.A25= | Silent (SNP) | VAF 54/308 reads (18%) | called by muse, mutect2, varscan2
- WDR87 | c.4791A>G p.Q1597= | Silent (SNP) | VAF 135/723 reads (19%) | called by muse, mutect2, varscan2
- XYLT1 | c.399T>A p.T133= | Silent (SNP) | VAF 61/444 reads (14%) | called by muse, mutect2, varscan2
- ALMS1P1 | n.770G>A | RNA (SNP) | VAF 14/185 reads (8%) | catalogued as rs560001939; called by muse, mutect2
- CLIP2 | c.2479+39G>A | Intron (SNP) | VAF 21/255 reads (8%) | called by muse, mutect2
- CR2 | c.1979-178T>A | Intron (SNP) | VAF 122/988 reads (12%) | called by muse, mutect2, varscan2
- CRAT | c.291+17T>C | Intron (SNP) | VAF 74/477 reads (16%) | called by muse, mutect2, varscan2
- DES | c.-16C>T | 5'UTR (SNP) | VAF 13/149 reads (9%) | catalogued as rs1352112807; called by muse, mutect2, varscan2
- KRBOX4 | c.253+12C>T | Intron (SNP) | VAF 82/576 reads (14%) | catalogued as rs182293910, COSV53342861; called by muse, mutect2, varscan2
- PMAIP1 | c.*50G>A | 3'UTR (SNP) | VAF 161/750 reads (21%) | called by muse, mutect2, varscan2
- PTPRK | c.495+234C>T | Intron (SNP) | VAF 82/598 reads (14%) | called by muse, mutect2, varscan2
- TRDN | c.484+1211A>T | Intron (SNP) | VAF 115/951 reads (12%) | called by muse, mutect2, varscan2
- WNT9B | chr17:46885050 A>C | 3'Flank (SNP) | VAF 37/226 reads (16%) | called by muse, mutect2, varscan2
